FM case AD9147 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/47abd159-5ac4-4ea8-ae90-373e67eae3ae

Female, 60.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the bladder; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
